CMI case MBCproject_0107 — CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/053a1c7a-6eb2-4c12-b31d-671dad71044d

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino.

Diagnoses (1)
1. Infiltrating lobular carcinoma, NOS: Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Age at diagnosis: 61.2 years (22,354 days).

Biospecimens (3 samples)
- Sample MBCproject_0107_SALIVA: Sample type: DNA; Tissue type: Normal; Specimen type: Saliva; Biospecimen anatomic site: Other.
- Samples MBCproject_0107_T1_RNA, MBCproject_0107_T1_WES (2 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
